Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7723, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7723-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description
		BR-7723	Stomach with the plate-like tumour, 12.5 cm; whole wall is invaded. Greater and lesser curvature lymph nodes are dense, hyperemic; omentum -- hyperemia.

[page 2 of 3]
Microscopic Description	Diagnosis Details	Formatted Path Report
Adenocarcinoma of the stomach, G3, with solid structure with ulceration and perigastric fat invasion. Fifteen lymph nodes were examined, eight lymph nodes demonstrated metastases, neuroendocrinal differentiation can be considered. Omentum -- normal structure.	Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:	STOMACH TISSUE CHECKLIST Specimen type: Total gastrectomy Tumor site: Stomach Tumor size: 12.5 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 8/15 positive for metastasis (Greater and lesser omentum 8/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
Date of Procurement

Source: NCI Genomic Data Commons file 22c58068-4c8d-452e-b9fa-72e131ea1276 (TCGA-BR-7723.5FA5D633-38B1-488D-BFFD-8173053F65AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).